Somatic mutation profile of tumor specimen TCGA-38-6178-01A (aliquot TCGA-38-6178-01A-11D-1753-08) from TCGA case TCGA-38-6178, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.1 years (25,593 days).
Specimen TCGA-38-6178-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe22b003-4498-4772-b50f-c597b2b4ba2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-38-6178-10A (Blood Derived Normal), aliquot TCGA-38-6178-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da51eb21-62b2-48f5-9f8c-a05248ac3c63

The open-access MAF lists 59 somatic variants for this specimen: 43 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 15, Nonsense Mutation 4, Frame Shift Del 2, In Frame Del 2, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 91/186 reads (49%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ACAT1 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 7/129 reads (5%) | catalogued as COSV54921852; called by muse, mutect2
- ANO2 | c.2444C>G p.A815G (on ENST00000356134 / NM_001278597.3; = p.A819G on NM_001278596.3) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV59035831; called by muse, mutect2
- ATP10D | c.1895G>A p.W632* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as COSV56708035, COSV56711101; called by muse, mutect2, varscan2
- C11orf16 | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55149385; called by muse, mutect2
- CDK7 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs755500732, COSV99841842; called by muse, mutect2
- CEP76 | c.311C>A p.T104K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV50868616; called by muse, mutect2
- CNTNAP5 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV70501796; called by muse, mutect2
- COL6A3 | c.2794G>T p.A932S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as rs112827048, COSV55101537; called by muse, mutect2, varscan2
- CROT | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 23/125 reads (18%) | catalogued as rs745924550, COSV58976101; called by muse, mutect2, varscan2
- CSF3R | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV58967588; called by muse, mutect2
- CSMD1 | c.3023C>T p.T1008M (on ENST00000520002; = p.T1007M on NM_033225.6) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs147113316, COSV59282026; called by muse, mutect2, varscan2
- DHRS2 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as COSV99159847; called by muse, mutect2
- EGLN3 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs1335076539, COSV51654547; called by muse, mutect2
- ESCO1 | c.812A>T p.N271I | Missense Mutation (SNP) | VAF 15/223 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52521709; called by muse, mutect2
- FAT1 | c.12215G>T p.G4072V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as COSV71674181, COSV71675360; called by muse, mutect2, varscan2
- GABRA4 | c.1132C>A p.Q378K | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.21); catalogued as rs1237493402, COSV51932590; called by muse, mutect2, varscan2
- GRIK3 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as rs569112734, COSV66144226; called by muse, mutect2, varscan2
- HSPB9 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs782420125, COSV56792222; called by muse, varscan2
- IL1RAPL2 | c.1376A>T p.D459V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61171825; called by muse, mutect2, varscan2
- KDM2B | c.2392G>A p.V798M | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs781861426, COSV65643605; called by muse, mutect2, varscan2
- LAMA3 | c.2509G>A p.D837N | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV100555596, COSV100557400, COSV58075359; called by muse, mutect2, varscan2
- MAP3K11 | c.1239G>C p.K413N | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58421120; called by muse, mutect2, varscan2
- MTG2 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.042); catalogued as COSV63694443; called by muse, mutect2, varscan2
- MYO6 | c.3482C>T p.P1161L (on ENST00000369981; = p.P1151L on NM_004999.4) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.234); catalogued as COSV64120501; called by muse, varscan2
- PEG3 | c.1244C>G p.P415R | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV55642359; called by muse, mutect2, varscan2
- PGM2 | c.910A>T p.T304S | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV67939338; called by muse, mutect2
- PTPN13 | c.5695G>T p.G1899* (on ENST00000411767 / NM_080683.3; = p.G1880* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV57413610; called by muse, mutect2
- SLC35B3 | c.750G>A p.M250I | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV59469345; called by muse, mutect2
- SPAG17 | c.2845G>A p.E949K | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as COSV60464506; called by muse, mutect2
- TGM2 | c.1118C>G p.P373R | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63932094; called by muse, mutect2
- TIE1 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs376549515, COSV65249615; called by muse, mutect2, varscan2
- TP53 | c.848G>C p.R283P | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs371409680, CM021154, COSV52693421, COSV52700134, COSV52964971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM72 | c.859G>C p.A287P | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV59069304; called by muse, mutect2
- UGT2B17 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV100497270; called by muse, mutect2, varscan2
- UTRN | c.9246-1G>T p.X3082_splice | Splice Site (SNP) | VAF 39/78 reads (50%) | catalogued as COSV62304952; called by muse, varscan2
- WDFY3 | c.9578A>G p.H3193R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1034570064, COSV55709960; called by muse, mutect2, varscan2
- ZNF281 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 8/195 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99664459; called by muse, mutect2
- ZNF549 | c.310C>T p.H104Y (on ENST00000376233 / NM_001199295.2; = p.H91Y on NM_153263.2) | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99558601; called by muse, mutect2, varscan2
- KCNS3 | c.930_934del p.R311Sfs*11 | Frame Shift Del (DEL) | VAF 33/126 reads (26%) | called by mutect2, pindel, varscan2
- KCNS3 | c.1107_1109del p.T370del | In Frame Del (DEL) | VAF 6/63 reads (10%) | called by mutect2, pindel, varscan2
- MAPK8IP3 | c.3018-47_3018del p.X1006_splice | Splice Site (DEL) | VAF 14/72 reads (19%) | called by mutect2, pindel
- SLC16A7 | c.886del p.A296Lfs*5 | Frame Shift Del (DEL) | VAF 9/91 reads (10%) | called by mutect2, pindel, varscan2
- ARAP3 | c.2157A>G p.A719= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1428666328, COSV53353152; called by muse, mutect2, varscan2
- CDKN2A | c.333C>T p.G111= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs1490202463, COSV58699867; ClinVar: uncertain significance; called by muse, mutect2
- CENPF | c.4281G>A p.Q1427= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV65277525; called by muse, mutect2
- GRIK3 | c.2235C>T p.Y745= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as rs763045219, COSV66138020; called by muse, mutect2, varscan2
- MYO18B | c.7104G>T p.P2368= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV59143311; called by muse, mutect2, varscan2
- NCOA6 | c.1152A>G p.S384= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV62866322; called by muse, mutect2
- QPCTL | c.879G>A p.R293= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as COSV99171307; called by muse, mutect2
- SFRP4 | c.564A>T p.A188= | Silent (SNP) | VAF 12/190 reads (6%) | catalogued as COSV71412561; called by muse, mutect2
- SGMS2 | c.1023T>G p.P341= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV62989506; called by muse, mutect2, varscan2
- TMEM167B | c.60C>G p.T20= | Silent (SNP) | VAF 97/498 reads (19%) | catalogued as COSV100597922; called by muse, mutect2, varscan2
- TPO | c.2070C>A p.S690= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100221035, COSV61107819; called by muse, mutect2, varscan2
- TPR | c.2223A>C p.S741= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV66603667; called by muse, mutect2
- USP24 | c.2763T>A p.L921= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV53774647; called by muse, mutect2, varscan2
- VAV3 | c.1863C>G p.A621= | Silent (SNP) | VAF 50/131 reads (38%) | catalogued as COSV100580165; called by muse, mutect2, varscan2
- ZAP70 | c.1533C>A p.I511= | Silent (SNP) | VAF 24/179 reads (13%) | catalogued as COSV53856177, COSV99385884; called by muse, mutect2, varscan2
- TTN | c.34264+2529G>A | Intron (SNP) | VAF 9/204 reads (4%) | catalogued as COSV60238776; called by muse, mutect2
